Somatic mutation profile of tumor specimen TCGA-FY-A2QD-01A (aliquot TCGA-FY-A2QD-01A-11D-A19J-08) from TCGA case TCGA-FY-A2QD, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 61.6 years (22,491 days).
Specimen TCGA-FY-A2QD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 46a5fb2c-d8c0-4162-ba73-11e53950387c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FY-A2QD-10A (Blood Derived Normal), aliquot TCGA-FY-A2QD-10A-01D-A19M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7ef85a16-e2f6-4292-b919-7cd07e2093dd

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 4, Silent 2, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DLGAP2 | c.3133G>A p.E1045K | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV70098324, COSV70101183; called by muse, mutect2
- HPS1 | c.829C>T p.H277Y | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated (0.68); PolyPhen benign (0.259); catalogued as COSV57269023; called by muse, mutect2
- MECP2 | c.379C>T p.P127S | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.232); catalogued as COSV57655435; called by muse, mutect2, varscan2
- SLC23A2 | c.1664C>A p.T555K | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.907); catalogued as COSV57776589; called by muse, mutect2, varscan2
- GABRB2 | c.540C>T p.S180= | Splice Region (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- SLCO1B3 | c.868del p.R290Efs*10 | Frame Shift Del (DEL) | VAF 17/65 reads (26%) | called by mutect2, pindel, varscan2
- ESX1 | c.369G>A p.P123= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as rs781900026, COSV65424796; called by muse, mutect2, varscan2
- STK38 | c.750C>T p.N250= | Silent (SNP) | VAF 119/311 reads (38%) | catalogued as COSV57709733; called by muse, mutect2, varscan2
